Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TI, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TI-01A (Primary Tumor).

[page 1 of 4]
Sample #

Gender: Male

DOB:

Race: Native Hawaiian/Other Pacific Islander

Report Date:

Pathology Report:

ICD-O-3
Carcinoma, urothelial NOS
8/20/13
Site C6CF
Anterior wall of bladder.
path C67.3
Overlapping lesion of
bladder C67.8
JW 7/22/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph node; dissection:

- One of ten lymph nodes, positive for metastatic urothelial carcinoma (1/10).
- Lymph nodal tumor focus measures 2.0 cm, with extranodal tumor extension.

B. Left pelvic lymph node; dissection:

- Eleven lymph nodes, no tumor (0/11).

C. Urinary bladder; cystoprostatectomy:

- Bladder with high grade urothelial carcinoma invading thru the muscularis propria and extending into the perivesical tissue and seminal vesicle, see pathologic parameters.
- Posterior margin is positive for urothelial carcinoma.
- Prostate with prostatic adenocarcinoma, see pathologic parameters.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue and seminal vesicle.
4. Tumor distribution: Solitary, 5.5 cm involving dome, right lateral wall, anterior wall and posterior wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Positive for urothelial carcinoma (1.3 cm).
8. Lymph nodes: Positive for tumor (1/21).
9. pTNM: pT4b,N1,MX, R1.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

[page 2 of 4]
Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+4=7
2. Perineural Invasion: Present.
3. Tumor Location: Peripheral zone - right and left.
4. Tumor Volume Estimate: 15%.
5. High-grade P.I.N.: Multifocal.
6. Seminal Vesicles: Negative for prostate carcinoma.
7. Extraprostatic Extension: Absent.
8. Peripheral Margin: Positive for tumor (right anterior, 0.1 mm).
9. Distal (apical) Margin: Negative for tumor.
10. Proximal (basilar) Margin: N/A.
11. Regional Lymph Nodes (right and left): Negative for prostate carcinoma (0/21).
12. pTNM: pT2c,N0,MX, R1.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, ☐ M.D., Ph.D.
Electronically Signed Out by ☐ MD

Clinical History:

The patient is a year-old male with history of high-grade urothelial carcinoma invasive into muscularis propria undergoing cystectomy and lymph node dissection.

Specimens Received:

- A: Right pelvic lymph node
- B: Left pelvic lymph node
- C: Bladder, vas deferens,

Gross Description:

The specimens are received in three containers each labeled with the patient's name and medical record number.

- A. The first container is additionally identified as, "right pelvic lymph node". Received in formalin are multiple fragments of yellow, lobulated fibroadipose tissue measuring 6.5 x 5.8 x 2.4 cm in aggregate. Multiple rubbery

[page 3 of 4]
lymph nodes are identified ranging from 0.3-5.5 cm in greatest dimension.

Representative sections of the specimen are submitted as follows:

A1: Multiple candidate lymph nodes

A2: One lymph node, bisected

A3-A5: One lymph node, trisected

A6-A10: One lymph node

B. The second container is additionally identified as, "left pelvic lymph node". Received in formalin are multiple fragments of yellow, lobulated fibroadipose tissue measuring 7.5 x 5 x 1.9 cm in aggregate. Multiple rubbery lymph nodes are identified ranging from 0.2-6 cm in greatest dimension.

Representative sections of the specimen are submitted as follows:

B1: Multiple candidate lymph nodes

B2: 2 lymph nodes, bisected

B3: One lymph node bisected

B4-B5: One lymph node, bisected

B6-B9: One lymph node, sectioned

C. The third container is additionally identified as, "bladder, vas deferens".

Received fresh and placed in formalin is a 301.8 g, 16 x 10.5 x 3.6 cm cystoprostatectomy specimen with attached mesenteric fat. The bladder measures 7.5 x 7 x 2.5 cm. The right ureteral stump measures 5 x 0.3 cm and the left 3 x 0.5 cm, and both demonstrate patent lumina. The prostate measures 4.2 x 3 x 2.9 cm. The right seminal vesicle measures 2.8 x 1.1 x 0.6 cm and the right vas deferens 8 x 0.5 cm. Detached vessels are also present measuring 5.2 and 5.5 cm in length by 0.3 cm in diameter. The left seminal vesicle measures 2.4 x 1 x 0.5 cm and the left vas deferens 12 x 0.5 cm. Plastic tubing is present in the bladder. There is disruption of the junction of the prostate and bladder along the right side of the specimen. The urethral stump is flush with the prostate apex. The right half of the prostate and bladder is inked blue and the left half is inked black. The prostate is opened anteriorly along the urethra and continued superiorly through the bladder in a Y-shaped incision. The prostate is serially sectioned from apex to base to reveal an ill-defined, yellow-tan, firm lesion measuring 1.8 x 0.9 x 0.6 cm in the right prostate measuring 0.1 cm from the margin. The bladder demonstrates a tan, fungating, ulcerated 5.5 x 5.5 cm mass involving the dome, right lateral wall, right half of the anterior wall and some of the right posterior wall. The right ureteral orifice is involved by the mass. Serial sectioning reveals ill-defined tumor invasion into the adipose tissue to a depth of 1.4 cm, extending to 0.2 cm of the inked margin. The remainder of the mucosa is tan-brown, edematous, and glistening with a uniform 0.2 cm wall thickness. The bilateral ureteral orifices are identified and probe patent. The perivesicular fat is extensively dissected for lymph nodes, but none are found. Representative sections are submitted as follows:

C1: Left ureteral margin

C2: Right ureteral margin

C3: Urethral and prostatic apical margin

[page 4 of 4]
C4-C6: Representative prostate, right half (with lesion)
C7-C9: Representative prostate, left half
C10: Right vas deferens and seminal vesicle
C11-c12: Left vas deferens and seminal vesicle
C13-C17: Mass (with deepest invasion in C14)
C18: Uninvolved left wall
C19: Mass and right ureteral orifice
C20: Additional distal urethral margin

Staging Discrepancy		✓
Stage/Synchronous Primary Sites	Prostate ✓	

Source: NCI Genomic Data Commons file 6b8b2afc-6d5f-4e29-942d-1fa309f81a73 (TCGA-FD-A6TI.9262DABE-98EE-4544-8907-124CDE5197C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).